Somatic mutation profile of tumor specimen 0D94V9 from CCDI case PBBHXT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.1 years (3,340 days).
Specimen 0D94V9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8d96b1c-b5fa-4219-b63d-f8a75d7bf2b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D94VA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a490ee44-e6f2-49ae-92f9-f453facf7f7f

The open-access MAF lists 7 somatic variants for this specimen: 2 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 2, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC102B | c.1425A>T p.K475N | Missense Mutation (SNP) | VAF 27/308 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.787); called by muse, mutect2
- HEPH | c.1105G>T p.A369S (on ENST00000343002; = p.A102S on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/776 reads (5%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2
- ACVR1B | c.471C>T p.H157= | Silent (SNP) | VAF 20/492 reads (4%) | called by muse, mutect2
- DUSP9 | c.159C>T p.R53= | Silent (SNP) | VAF 28/494 reads (6%) | called by muse, mutect2
- FAM166C | c.363T>C p.H121= | Silent (SNP) | VAF 88/250 reads (35%) | called by muse, mutect2
- KIAA1755 | c.*66G>A | 3'UTR (SNP) | VAF 6/115 reads (5%) | called by muse, mutect2
- MIA2 | chr14:39234090 G>A | 5'Flank (SNP) | VAF 8/222 reads (4%) | called by muse, mutect2
